Gene-level copy-number profile of tumor specimen AP-9PXS-FN from APOLLO case AP-9PXS, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-9PXS-FN: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82d8d885-9d49-4819-960d-12df0af66063.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-9PXS-RB (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/db78dffc-bb93-444c-b88b-fad807aba395

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 18,400; copy number 2: 34,985; copy number 3: 4,929; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–21,031,640, 1 gene: HACD4.
- chr9:21,638,285–25,089,151, 35 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr15:34,379,068–34,521,791, 8 genes: GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–1): MIR1233-2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
